CPTAC case C3L-09206 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7b25e2c8-752c-4e16-8c7d-76d9abc7310f

Demographics
Sex at birth: male; Race: white; Year of birth: 1954; Vital status: Alive; Country of birth: Romania.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 67.2 years (24,559 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 386 days (1.1 years); Progression or recurrence: no; Days to last follow up: 386 days (1.1 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 1.8 cm; Lymph nodes tested: 52.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 61 days; Days to treatment end: 83 days; Treatment outcome: Stable Disease.

Follow-up (1 entry)
- Days to follow up: 386 days (1.1 years); Disease response: Stable Disease; Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 20; Cigarettes per day: 20; Tobacco smoking onset year: 2001; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09206-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 50 days; Initial weight: 49 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09206-24: Section location: Stomach, NOS; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-09206-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 50 days; Initial weight: 72 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09206-25: Section location: Stomach, NOS; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-09206-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 50 days; Method of sample procurement: Blood Draw.
